Somatic mutation profile of tumor specimen 0DTGDB from CCDI case PBCJJF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 12.5 years (4,563 days).
Specimen 0DTGDB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a23f5913-d263-40e8-96c4-9331c8596d0c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTGDG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/202cb412-53c7-45e6-8326-50070df12d2c

The open-access MAF lists 40 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, Nonsense Mutation 5, Intron 3, RNA 1, 5'Flank 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.109T>C p.S37P | Missense Mutation (SNP) | VAF 266/633 reads (42%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121913228, COSV62688488, COSV62688537, COSV62706597; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PBX1 | c.550C>T p.R184* | Nonsense Mutation (SNP) | VAF 468/1050 reads (45%) | catalogued as rs1553248081, COSV63342742; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABL1 | c.1901G>T p.G634V | Missense Mutation (SNP) | VAF 228/614 reads (37%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.001); catalogued as COSV59323776; called by mutect2, varscan2
- BACH2 | c.1584C>G p.Y528* | Nonsense Mutation (SNP) | VAF 46/514 reads (9%) | catalogued as COSV57595357; called by muse, mutect2
- CD300C | c.590G>A p.S197N | Missense Mutation (SNP) | VAF 428/927 reads (46%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.858); catalogued as COSV100423250; called by muse, mutect2, varscan2
- CYP3A7 | c.388C>T p.R130* | Nonsense Mutation (SNP) | VAF 349/890 reads (39%) | catalogued as rs766477991, COSV100312499; called by muse, mutect2, varscan2
- FLG | c.1550G>A p.R517H | Missense Mutation (SNP) | VAF 124/400 reads (31%) | SIFT tolerated (0.88); PolyPhen benign (0.053); catalogued as rs553216612, COSV64241500; called by muse, mutect2, varscan2
- FREM1 | c.3425A>G p.N1142S | Missense Mutation (SNP) | VAF 38/962 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs964990156, COSV66528942; called by muse, mutect2
- FTHL17 | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 251/572 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.618); catalogued as COSV63266585; called by muse, mutect2, varscan2
- ITPR3 | c.2791C>T p.R931C | Missense Mutation (SNP) | VAF 313/329 reads (95%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs760213672, COSV65415398; called by muse, mutect2, varscan2
- JAG1 | c.2927C>T p.T976M | Missense Mutation (SNP) | VAF 315/778 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs751809412; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LATS2 | c.2368C>T p.R790* | Nonsense Mutation (SNP) | VAF 35/534 reads (7%) | catalogued as COSV66874412; called by muse, mutect2
- MAGEB1 | c.44G>A p.R15H | Missense Mutation (SNP) | VAF 476/1032 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.828); catalogued as rs993232251, COSV100975005; called by muse, mutect2, varscan2
- POU4F2 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 576/1095 reads (53%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.914); catalogued as rs1458753264; called by muse, mutect2, varscan2
- PTCHD1 | c.1603G>A p.A535T | Missense Mutation (SNP) | VAF 373/768 reads (49%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV65060313; called by muse, mutect2, varscan2
- SMARCA4 | c.2681C>T p.T894M | Missense Mutation (SNP) | VAF 45/1477 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60797538; called by muse, mutect2
- SMARCA4 | c.2758G>A p.E920K | Missense Mutation (SNP) | VAF 44/887 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV60786870; called by muse, mutect2
- TJP1 | c.3200C>T p.T1067M | Missense Mutation (SNP) | VAF 210/506 reads (42%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.013); catalogued as rs750184846, COSV62040088; called by muse, mutect2, varscan2
- TRIO | c.3509C>T p.S1170F | Missense Mutation (SNP) | VAF 117/1644 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as COSV100710172, COSV60096029; called by muse, mutect2
- DDX3X | c.1604G>A p.G535E (on ENST00000399959; = p.G536E on NM_001356.5) | Missense Mutation (SNP) | VAF 422/951 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLGAP2 | c.973C>A p.H325N | Missense Mutation (SNP) | VAF 285/673 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- GLRA3 | c.931T>A p.S311T | Missense Mutation (SNP) | VAF 156/388 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LRBA | c.7033A>G p.R2345G | Missense Mutation (SNP) | VAF 48/1732 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2
- NCKAP5 | c.4564A>G p.S1522G | Missense Mutation (SNP) | VAF 503/1127 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- NOS2 | c.1101C>G p.C367W | Missense Mutation (SNP) | VAF 252/639 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTPRF | c.4542G>C p.W1514C | Missense Mutation (SNP) | VAF 44/780 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- TRIM33 | c.1228A>T p.K410* | Nonsense Mutation (SNP) | VAF 54/984 reads (5%) | called by muse, mutect2
- CSNK2B | c.609C>T p.A203= | Silent (SNP) | VAF 389/404 reads (96%) | called by muse, mutect2, varscan2
- CT47B1 | c.552C>T p.G184= | Silent (SNP) | VAF 37/576 reads (6%) | catalogued as rs751300926, COSV64890475; called by muse, mutect2
- GOLM2 | c.798C>G p.P266= | Silent (SNP) | VAF 16/464 reads (3%) | catalogued as COSV55465336; called by muse, mutect2
- PIEZO1 | c.2052C>T p.I684= | Silent (SNP) | VAF 263/551 reads (48%) | catalogued as COSV56343649; called by muse, mutect2, varscan2
- PLEKHM3 | c.360C>T p.F120= | Silent (SNP) | VAF 94/455 reads (21%) | called by muse, mutect2, varscan2
- UROC1 | c.489C>T p.G163= | Silent (SNP) | VAF 405/927 reads (44%) | called by muse, mutect2, varscan2
- BTG1 | chr12:92145948 A>T | 5'Flank (SNP) | VAF 38/106 reads (36%) | called by muse, mutect2, varscan2
- HERC1 | c.13689-48A>T | Intron (SNP) | VAF 12/96 reads (13%) | called by muse, mutect2
- MUC19 | n.19276G>T | RNA (SNP) | VAF 116/330 reads (35%) | called by muse, mutect2, varscan2
- NTN1 | c.*24C>T | 3'UTR (SNP) | VAF 65/196 reads (33%) | catalogued as rs972721960; called by muse, mutect2
- SLC25A18 | c.20+432G>A | Intron (SNP) | VAF 57/124 reads (46%) | catalogued as rs777041645; called by muse, mutect2, varscan2
- SMARCA2 | c.4738-89dup | Intron (INS) | VAF 22/50 reads (44%) | catalogued as rs1345794048; called by mutect2, varscan2
- TSR3 | c.-33G>A | 5'UTR (SNP) | VAF 21/43 reads (49%) | catalogued as rs962248757; called by muse, mutect2, varscan2
